Gene-level copy-number profile of tumor specimen TCGA-AC-A23C-01A from TCGA case TCGA-AC-A23C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.3 years (22,751 days).
Specimen TCGA-AC-A23C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2036be70-c64b-4ef4-82c6-822c5afae946.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A23C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd927c83-c804-4dad-8e1d-ab6797731f02

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,333; copy number 2: 47,382; copy number 3: 3,538; copy number 4: 565; copy number 5: 38; copy number 6: 1,543; copy number 7: 111; copy number 8: 48; copy number 9: 1; copy number 10: 32; copy number 11: 114; copy number 12: 16; copy number 13: 14; copy number 16: 18; copy number 17: 28; copy number 22: 18; copy number 32: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A23C-01A-12D-A166-01): tumor purity 0.48, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,998 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:177,392,667–248,919,946, 1,450 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:1,601,654–1,613,897, 2 genes, copy number 7: FOXCUT, FOXC1.
- chr6:12,290,361–21,232,404, 118 genes, copy number 11–32 (within-gene range 4–32) (broad region; genes not listed).
- chr6:21,822,536–21,822,737, 1 gene, copy number 12: AL136313.1.
- chr6:22,744,395–23,031,780, 1 gene, copy number 9 (within-gene range 4–9): AL035401.1.
- chr6:25,962,802–26,045,869, 14 genes, copy number 13 (within-gene range 4–13): TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3.
- chr6:32,549,940–33,239,690, 45 genes, copy number 7: RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1.
- chr6:37,819,727–38,154,624, 1 gene, copy number 7 (within-gene range 2–7): ZFAND3.
- chr6:38,002,832–38,003,313, 1 gene, copy number 7: AL589655.1.
- chr6:38,207,274–38,207,345, 1 gene, copy number 7: AL033518.1.
- chr17:39,461,486–39,877,896, 18 genes, copy number 16: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr18:26,098,839–28,824,826, 39 genes, copy number 5–17: RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1.
- chr18:30,713,275–37,992,413, 120 genes, copy number 7–17 (broad region; genes not listed).
- chr18:39,034,007–39,800,322, 9 genes, copy number 8 (within-gene range 2–8): RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.
- chr18:50,879,080–52,339,025, 17 genes, copy number 8: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1.
- chr18:52,409,042–52,419,644, 2 genes, copy number 8: AC011155.1, VN1R76P.
- chr18:54,142,133–54,959,461, 19 genes, copy number 6–7: AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P.
- chr18:60,329,190–60,654,623, 6 genes, copy number 5 (within-gene range 1–5): AC091576.1, MC4R, AC010928.2, MRPS5P4, AC010928.3, AC010928.1.
- chr18:61,333,430–61,607,006, 5 genes, copy number 6: CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1.
- chr18:61,808,067–64,019,779, 39 genes, copy number 6–7 (within-gene range 1–7): RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8.
- chr18:64,072,158–64,149,088, 2 genes, copy number 7 (within-gene range 3–7): RPL12P39, LINC00305.
- chr20:49,812,713–54,269,542, 88 genes, copy number 6–8 (within-gene range 1–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,333. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
